Somatic mutation profile of tumor specimen TCGA-ZG-A9LS-01A (aliquot TCGA-ZG-A9LS-01A-12D-A41K-08) from TCGA case TCGA-ZG-A9LS, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.4 years (23,540 days).
Specimen TCGA-ZG-A9LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b06c2c6-117f-4bfe-a855-0747066bd032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LS-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LS-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386bbf76-abf5-46b0-a394-7aa45c5948ca

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs182925368, COSV52193468; called by muse, varscan2
- ANKRD11 | c.4529C>T p.P1510L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs770592504, COSV99969950, COSV99970078; called by muse, mutect2, varscan2
- CALCR | c.1346C>T p.A449V (on ENST00000649521 / NM_001164737.2; = p.A433V on NM_001742.4) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.64); catalogued as rs780358113, COSV64010215; called by muse, mutect2, varscan2
- CTNNAL1 | c.640-1G>C p.X214_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100336644; called by muse, mutect2, varscan2
- CTTNBP2 | c.4387C>T p.R1463C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779662827, COSV99354412; called by muse, mutect2, varscan2
- DOCK2 | c.3436G>T p.D1146Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56980007, COSV99913951; called by muse, mutect2, varscan2
- FGG | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs1046557134, COSV60194420; called by muse, mutect2, varscan2
- HGS | c.2080A>G p.M694V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61267151; called by muse, mutect2, varscan2
- IQCF2 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.925); catalogued as COSV100291074; called by muse, mutect2, varscan2
- ITGA7 | c.1805C>T p.S602L (on ENST00000555728; = p.S558L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs548594784, COSV99149238, COSV99157235; called by muse, mutect2, varscan2
- MAMDC4 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.771); catalogued as rs772204286, COSV99915776; called by muse, varscan2
- PKD1 | c.9550G>C p.V3184L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99238587; called by muse, mutect2, varscan2
- PTK7 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.582); catalogued as COSV100030136, COSV100030423; called by muse, mutect2, varscan2
- SLC5A10 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1046841367, COSV100525319; called by muse, mutect2, varscan2
- TLE3 | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV100450654; called by muse, mutect2, varscan2
- CNOT1 | c.402_407delinsA p.N135Ffs*6 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by pindel, varscan2*
- MCOLN3 | c.866_874del p.D289_F291del | In Frame Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel, varscan2
- PPIA | c.291del p.L98Cfs*35 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- CD22 | c.1521C>T p.D507= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs757060882, COSV50049513; called by muse, mutect2, varscan2
- MAMDC4 | c.591C>T p.T197= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV99915778; called by muse, varscan2
- PCDHGB4 | c.1971G>A p.T657= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV53986868; called by muse, mutect2, varscan2
- UROC1 | c.1614G>A p.P538= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs750426480, COSV99331933; called by muse, mutect2, varscan2
- UTP4 | c.687G>A p.V229= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs1210142351, COSV100077072; called by muse, mutect2, varscan2
- DST | c.4297-1185G>A | Intron (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99758264; called by muse, mutect2, varscan2
